HCMI case HCM-BROD-0649-C49 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2c0409da-a354-4e40-bb7c-442f454aca8b

Demographics
Sex at birth: female; Year of birth: 1967.

Diagnoses (2)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.9; Tissue or organ of origin: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 48.5 years (17,713 days); Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,247 days (3.4 years); Days to treatment end: 1,294 days (3.5 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Metastasis of the uterus (histology not recorded by GDC). ICD-10 code: C78.8; Site of resection or biopsy: Abdomen, NOS; Age at diagnosis: 51.7 years (18,889 days); Days to diagnosis: 1,176 days (3.2 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Rivaroxaban; Treatment intent type: Maintenance Therapy; Days to treatment start: 214 days; Days to treatment end: 1,170 days (3.2 years); Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Days to follow up: 1,299 days (3.6 years); Disease response: Stable Disease; Progression or recurrence: No.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 47.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0649-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0649-C49-06A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0649-C49-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0649-C49-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 6.
